Gene-level copy-number profile of tumor specimen TCGA-14-0862-01B from TCGA case TCGA-14-0862, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 60.7 years (22,179 days).
Specimen TCGA-14-0862-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.978efd5c-10ea-4155-a2e5-b696f3e723d7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-14-0862-10C (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/169b002f-2404-419f-bd88-a4d4e44be3d0

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 75; copy number 2: 18,515; copy number 3: 821; copy number 4: 40,354; copy number 5: 48.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-14-0862-01B-01D-1842-01): tumor purity 0.68, ploidy 1.72, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 75 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:14,317,073–14,358,490, 1 gene: AL136366.1.
- chr9:21,524,307–27,944,497, 70 genes (broad region; genes not listed).
- chr9:28,148,211–28,149,236, 1 gene: AL451124.1.
- chr17:31,272,013–31,318,831, 3 genes (within-gene range 0–2): OMG, EVI2B, AC134669.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
